Surgical pathology report (de-identified scan), TCGA case TCGA-06-0166, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0166-01A (Primary Tumor).

TCGA-06-0166

PATH. NO. 1

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, RIGHT OCCIPITAL, EXCISION: GLIOBLASTOMA MULTIFORME.
MIB-1 PROLIFERATION INDICES: 12% AND 14%.

SEE MICROSCOPIC.

Operation/Specimen: Brain, craniotomy.

GROSS PATHOLOGY:

A. Received fresh, two fragments, 3 x 2 x 0.9 cm. Soft, focally necrotic and hemorrhagic. In total #1-4.

INTRAOPERATIVE CONSULTATION:

1. Brain, imprint: Atypical cells.
2. Brain, squash preparations: Glioma, high histological grade.

B.
SPECIMEN: 2, brain tumor.
FIXATIVE: Saline.
GENERAL: Three irregularly shaped fragments of tan-red to glistening tan brain tissue, measuring 1.0 x 1.0 x 0.6 cm., 1.5 x 1.2 x .8 cm., and 3.0 x 1.5 x 1.2 cm.
SECTIONS: All submitted; 3 - smaller fragment, 4 - intermediate fragment, 5-7 - largest fragment.

MICROSCOPIC: A,B. Portions of a neoplastic proliferation of glial cells with an overall astrocytic phenotype. The neoplasm has solid areas and diffusely infiltrates the surrounding brain. The neoplastic cells have nuclear anaplastic features, and there are associated mitotic figures, prominent microvascular cellular proliferation, and areas of necrosis some of them with pseudopallisading.

SPECIAL STAINS: An immunoperoxidase method for MIB-1 was performed on sections from blocks 1 and 2. In the more cellular areas, a MIB-1 proliferation index of 14% and 12%, respectively, were determined in the more active areas.

Source: NCI Genomic Data Commons file e02786eb-8abb-456a-80ab-fcff4b9db6d8 (TCGA-06-0166.8C5FD571-8B2C-4360-9014-2E96833E8EC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).